Somatic mutation profile of tumor specimen HCM-BROD-0231-C25-86N (aliquot HCM-BROD-0231-C25-86N-01D-A937-36) from HCMI case HCM-BROD-0231-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 68.9 years (25,156 days).
Specimen HCM-BROD-0231-C25-86N: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6e61485-aeea-4c92-8c9d-149ffa94c7b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0231-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0231-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e30370b-8061-4e11-b15c-9c8a768b1493

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, In Frame Del 2, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 135/135 reads (100%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ARID1A | c.3391C>G p.Q1131E | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV61376561, COSV61380004; called by mutect2, varscan2
- BSN | c.7165C>T p.R2389W | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776078996; called by muse, mutect2
- CARD11 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 196/380 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs1298741148, COSV67802261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAN2A1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.152); catalogued as rs1359989748; called by muse, mutect2, varscan2
- NEB | c.11560G>C p.D3854H | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50881854, COSV51436297; called by muse, mutect2
- NRXN1 | c.1769C>A p.S590Y | Missense Mutation (SNP) | VAF 133/271 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100453687; called by muse, mutect2, varscan2
- POTEJ | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 114/380 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs764378487; called by muse, mutect2, varscan2
- SEC61A1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 177/378 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs767658338, COSV54578190; called by muse, mutect2, varscan2
- SHMT2 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 190/375 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs760592358, COSV61073422; called by muse, mutect2, varscan2
- SLC6A9 | c.1653C>T p.Y551= (on ENST00000360584 / NM_201649.4; = p.Y497= on NM_006934.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 125/258 reads (48%) | catalogued as rs200915117, COSV62212040; called by muse, mutect2, varscan2
- SLFN14 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 142/272 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1274661246; called by muse, mutect2, varscan2
- TBC1D10B | c.1489C>T p.L497F | Missense Mutation (SNP) | VAF 171/371 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374035939, COSV59768069; called by muse, mutect2, varscan2
- USH2A | c.9526C>A p.P3176T | Missense Mutation (SNP) | VAF 132/319 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.261); catalogued as COSV56356532; called by muse, mutect2, varscan2
- ARID1A | c.3398_3401del p.P1133Lfs*27 | Frame Shift Del (DEL) | VAF 185/204 reads (91%) | called by pindel, varscan2
- ATP1A4 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 169/335 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRAF | c.1577_1591del p.N526_P530del (on ENST00000288602 / NM_001374244.1; = p.N486_P490del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 89/247 reads (36%) | called by mutect2, pindel, varscan2
- C11orf80 | c.1838A>G p.Q613R | Missense Mutation (SNP) | VAF 237/468 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); called by muse, mutect2
- C12orf42 | c.839T>C p.M280T | Missense Mutation (SNP) | VAF 309/643 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DHX40 | c.1490G>A p.C497Y | Missense Mutation (SNP) | VAF 153/347 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- DOP1B | c.3961A>T p.S1321C | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2
- EPS8L2 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 164/355 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA1 | c.430A>G p.K144E | Missense Mutation (SNP) | VAF 101/231 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LRRFIP2 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 128/128 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MAGI2 | c.2969A>G p.D990G | Missense Mutation (SNP) | VAF 161/393 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTR | c.2519T>A p.M840K | Missense Mutation (SNP) | VAF 144/289 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMPCA | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 216/443 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP1R36 | c.424_426del p.T142del | In Frame Del (DEL) | VAF 114/128 reads (89%) | called by pindel, varscan2
- SLCO3A1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 157/303 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRIM3 | c.1391A>T p.K464M | Missense Mutation (SNP) | VAF 149/395 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- TRIM31 | c.12dup p.Q5Afs*81 | Frame Shift Ins (INS) | VAF 154/218 reads (71%) | called by mutect2, pindel, varscan2
- USF3 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 218/441 reads (49%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR12 | c.360T>A p.D120E | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX4 | c.4022T>G p.V1341G | Missense Mutation (SNP) | VAF 177/382 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- BCAR1 | c.1584T>C p.N528= | Silent (SNP) | VAF 202/411 reads (49%) | called by muse, mutect2, varscan2
- CR2 | c.2172G>T p.V724= | Silent (SNP) | VAF 140/294 reads (48%) | called by muse, mutect2, varscan2
- LAS1L | c.1932C>T p.D644= | Silent (SNP) | VAF 16/210 reads (8%) | catalogued as rs748382959, COSV56706596; called by muse, mutect2
- MACF1 | c.13368C>G p.R4456= (on ENST00000372915; = p.R2389= on NM_012090.5) | Silent (SNP) | VAF 320/320 reads (100%) | called by muse, mutect2, varscan2
- PDGFRA | c.2985C>T p.N995= | Silent (SNP) | VAF 213/427 reads (50%) | catalogued as rs138801854; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC25A45 | c.609G>A p.T203= | Silent (SNP) | VAF 130/257 reads (51%) | catalogued as rs370780233; called by muse, mutect2, varscan2
- SLC8A1 | c.1674G>A p.V558= | Silent (SNP) | VAF 24/506 reads (5%) | catalogued as COSV60478824; called by muse, mutect2
- SMARCA1 | c.948A>C p.I316= | Silent (SNP) | VAF 16/189 reads (8%) | called by muse, mutect2
- TBC1D25 | c.522C>T p.G174= | Silent (SNP) | VAF 136/147 reads (93%) | called by muse, mutect2, varscan2
- TBX4 | c.939C>T p.L313= | Silent (SNP) | VAF 258/516 reads (50%) | catalogued as rs777644345, COSV53606573, COSV53610218; called by muse, mutect2, varscan2
- GH2 | c.457-33C>A | Intron (SNP) | VAF 184/478 reads (38%) | catalogued as COSV60426287, COSV60426704; called by muse, mutect2
- TBC1D29P | n.2788G>A | RNA (SNP) | VAF 163/349 reads (47%) | catalogued as rs761058128, COSV70434072; called by muse, varscan2
